Somatic mutation profile of tumor specimen TCGA-58-8386-01A (aliquot TCGA-58-8386-01A-11D-2293-08) from TCGA case TCGA-58-8386, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IV; Age at diagnosis: 75.2 years (27,455 days).
Specimen TCGA-58-8386-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3b49fb63-e510-40fe-9323-2b5dcda569fb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-58-8386-10A (Blood Derived Normal), aliquot TCGA-58-8386-10A-01D-2293-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/09115394-4f14-48f7-af66-99549acd74c7

The open-access MAF lists 274 somatic variants for this specimen: 207 protein-altering or splice-affecting, 61 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 172, Silent 61, Nonsense Mutation 13, Splice Site 8, Frame Shift Del 5, Frame Shift Ins 5, RNA 5, In Frame Del 2, Splice Region 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DDX3X | c.133C>T p.R45* (on ENST00000399959; = p.R46* on NM_001356.5) | Nonsense Mutation (SNP) | VAF 34/57 reads (60%) | catalogued as rs1569234653, CM158020, COSV101302319; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.818G>T p.R273L | Missense Mutation (SNP) | VAF 17/43 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADAMTS12 | c.4171T>C p.C1391R | Missense Mutation (SNP) | VAF 38/304 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100711573, COSV61265839; called by muse, mutect2, varscan2
- ADGRL3 | c.2411G>T p.G804V (on ENST00000506720 / NM_001322402.2; = p.G736V on NM_015236.6) | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.049); catalogued as COSV101547371; called by muse, mutect2, varscan2
- AGTPBP1 | c.313T>G p.L105V | Missense Mutation (SNP) | VAF 47/180 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.167); catalogued as COSV100430142; called by muse, mutect2, varscan2
- ALCAM | c.809G>A p.C270Y | Missense Mutation (SNP) | VAF 30/308 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV100065508; called by muse, mutect2
- ALCAM | c.810C>A p.C270* | Nonsense Mutation (SNP) | VAF 30/312 reads (10%) | catalogued as COSV100065512; called by muse, mutect2
- ALG10 | c.904dup p.S302Ffs*9 | Frame Shift Ins (INS) | VAF 24/212 reads (11%) | catalogued as rs779782051; called by mutect2, varscan2
- AMBRA1 | c.3782C>T p.P1261L (on ENST00000458649 / NM_001367468.1; = p.P1171L on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV54061620; called by muse, mutect2, varscan2
- ANXA13 | c.804G>C p.L268F | Missense Mutation (SNP) | VAF 15/168 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1393642915, COSV51626730, COSV99146765; called by muse, mutect2
- APLNR | c.108G>T p.M36I | Missense Mutation (SNP) | VAF 16/188 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV99951625; called by muse, mutect2
- AQP12B | c.190C>A p.L64I (on ENST00000621682; = p.L76I on NM_001102467.2) | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.762); catalogued as COSV101315921; called by muse, mutect2, varscan2
- ASMT | c.691G>A p.D231N (on ENST00000381229; = p.D259N on NM_004043.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 76/302 reads (25%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV101172517; called by muse, mutect2, varscan2
- ATP10D | c.1120T>C p.W374R | Missense Mutation (SNP) | VAF 91/409 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99906102; called by muse, mutect2, varscan2
- BBS7 | c.721A>G p.I241V | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as COSV99145059; called by muse, mutect2, varscan2
- BICD1 | c.1325A>T p.N442I | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.939); catalogued as COSV99862884; called by muse, mutect2, varscan2
- CACNA1E | c.4698C>A p.N1566K | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT tolerated (0.29); PolyPhen benign (0.089); catalogued as COSV100704794; called by muse, mutect2, varscan2
- CACNA1F | c.2569A>G p.T857A | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.441); catalogued as COSV100545300; called by muse, mutect2, varscan2
- CAPN6 | c.1485-1G>A p.X495_splice | Splice Site (SNP) | VAF 45/251 reads (18%) | catalogued as COSV100137035; called by muse, mutect2, varscan2
- CARD17 | c.196G>T p.A66S | Missense Mutation (SNP) | VAF 24/119 reads (20%) | SIFT tolerated (0.35); PolyPhen benign (0.028); catalogued as rs773739591, COSV100995276; called by muse, mutect2, varscan2
- CCKBR | c.402G>A p.M134I | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.407); catalogued as rs1564888062, COSV100583076; called by muse, mutect2, varscan2
- CD96 | c.1226C>A p.A409E (on ENST00000283285 / NM_198196.3; = p.A393E on NM_005816.5) | Missense Mutation (SNP) | VAF 37/156 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV99343482; called by muse, mutect2, varscan2
- CDH5 | c.545C>T p.T182I | Missense Mutation (SNP) | VAF 28/206 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV100439404; called by muse, mutect2, varscan2
- CDH7 | c.1966G>T p.E656* | Nonsense Mutation (SNP) | VAF 22/63 reads (35%) | catalogued as COSV100543084; called by muse, mutect2, varscan2
- CDK5RAP1 | c.976G>A p.E326K (on ENST00000357886 / NM_001365728.1; = p.E312K on NM_016082.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 32/169 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.133); catalogued as COSV100212265, COSV59426597; called by muse, mutect2, varscan2
- CELSR1 | c.8834C>T p.T2945M | Missense Mutation (SNP) | VAF 17/123 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.732); catalogued as rs761231250, COSV99419742; called by muse, mutect2, varscan2
- CFAP299 | c.484A>G p.N162D | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100812330; called by muse, mutect2, varscan2
- CILK1 | c.1030C>A p.P344T | Missense Mutation (SNP) | VAF 10/158 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.101); catalogued as COSV100607985; called by muse, mutect2
- CLGN | c.1015G>A p.G339R | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100346792; called by muse, mutect2, varscan2
- COL15A1 | c.1371C>A p.D457E | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV100897929; called by muse, mutect2, varscan2
- COLEC12 | c.2129G>T p.G710V | Missense Mutation (SNP) | VAF 83/318 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101232148; called by muse, mutect2, varscan2
- CSMD3 | c.8920G>C p.V2974L (on ENST00000297405 / NM_001363185.1; = p.V2805L on NM_052900.3) | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.993); catalogued as COSV99845326; called by muse, mutect2
- CSTF2 | c.995G>C p.G332A | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100880862; called by muse, mutect2, varscan2
- CTNNA1 | c.1358C>T p.S453F | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.57); catalogued as COSV100243190; called by muse, mutect2, varscan2
- CUBN | c.2311G>A p.G771S | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.886); catalogued as rs866820343, COSV100913401; called by muse, mutect2, varscan2
- CYTH4 | c.631G>T p.E211* | Nonsense Mutation (SNP) | VAF 49/98 reads (50%) | catalogued as COSV99958131; called by muse, mutect2, varscan2
- DCC | c.2359G>T p.E787* | Nonsense Mutation (SNP) | VAF 10/36 reads (28%) | catalogued as COSV100502471; called by muse, mutect2
- DCDC1 | c.814G>A p.D272N | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.964); catalogued as COSV100664093; called by muse, mutect2
- DDX28 | c.1558C>T p.R520C | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1330804119, COSV60106330; called by muse, mutect2, varscan2
- DDX58 | c.847A>T p.K283* | Nonsense Mutation (SNP) | VAF 19/59 reads (32%) | catalogued as COSV101153183, COSV65883629; called by muse, mutect2, varscan2
- DEFB118 | c.157G>T p.A53S | Missense Mutation (SNP) | VAF 41/162 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.017); catalogued as COSV99489323; called by muse, mutect2, varscan2
- DGKI | c.2566G>T p.D856Y | Missense Mutation (SNP) | VAF 35/146 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.342); catalogued as COSV99936894; called by muse, mutect2, varscan2
- DNAH7 | c.11434G>C p.G3812R | Missense Mutation (SNP) | VAF 14/168 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100417086; called by muse, mutect2
- DNAJC2 | c.852G>T p.K284N | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV99971943; called by muse, mutect2, varscan2
- DYSF | c.2643+2T>C p.X881_splice | Splice Site (SNP) | VAF 37/141 reads (26%) | catalogued as rs146807631, CS066634, CS105929; called by muse, mutect2, varscan2
- E4F1 | c.1310G>T p.C437F | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1342663675, COSV100066047; called by muse, varscan2
- EHBP1 | c.3415C>T p.L1139= | Splice Region (SNP) | VAF 11/139 reads (8%) | catalogued as COSV99861675; called by muse, mutect2
- EPOR | c.402C>G p.H134Q | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.671); catalogued as COSV99710278; called by muse, mutect2, varscan2
- FAM169A | c.589C>T p.H197Y | Missense Mutation (SNP) | VAF 56/171 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.253); catalogued as COSV100998401; called by muse, mutect2, varscan2
- FAM177B | c.35A>T p.E12V | Missense Mutation (SNP) | VAF 17/131 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.624); catalogued as COSV100680454; called by muse, mutect2, varscan2
- FAN1 | c.2497G>T p.G833C | Missense Mutation (SNP) | VAF 48/260 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as COSV100756064; called by muse, mutect2, varscan2
- FAT1 | c.458C>T p.S153L | Missense Mutation (SNP) | VAF 31/253 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.477); catalogued as COSV101499606; called by muse, mutect2, varscan2
- FATE1 | c.342-2A>T p.X114_splice | Splice Site (SNP) | VAF 102/227 reads (45%) | catalogued as COSV100948198; called by muse, mutect2, varscan2
- FBXO10 | c.2347G>T p.G783W | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99447162; called by muse, mutect2, varscan2
- FIP1L1 | c.505+1G>A p.X169_splice | Splice Site (SNP) | VAF 23/103 reads (22%) | catalogued as COSV100184661; called by muse, mutect2, varscan2
- FLNA | c.1509C>A p.F503L | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); catalogued as COSV100775099; called by muse, mutect2, varscan2
- FOXG1 | c.1331C>A p.S444* | Nonsense Mutation (SNP) | VAF 11/90 reads (12%) | catalogued as COSV100486795, COSV100487027; called by muse, mutect2, varscan2
- FSCB | c.578G>A p.S193N | Missense Mutation (SNP) | VAF 76/280 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.282); catalogued as COSV100469764, COSV61217157, COSV61219673; called by muse, mutect2, varscan2
- GOLGB1 | c.6008A>G p.N2003S | Missense Mutation (SNP) | VAF 69/359 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs747604131, COSV100511430; called by muse, mutect2, varscan2
- GOLIM4 | c.1951A>G p.K651E | Missense Mutation (SNP) | VAF 7/135 reads (5%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.997); catalogued as COSV100463365; called by muse, mutect2
- GPANK1 | c.598C>T p.H200Y | Missense Mutation (SNP) | VAF 43/109 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.377); catalogued as COSV100789046; called by muse, mutect2, varscan2
- GPRIN3 | c.1588A>G p.T530A | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs769120919, COSV100310954; called by muse, mutect2, varscan2
- GRID1 | c.1454A>T p.Y485F | Missense Mutation (SNP) | VAF 74/198 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); catalogued as COSV100026094; called by muse, mutect2, varscan2
- GRID2 | c.166G>C p.E56Q | Missense Mutation (SNP) | VAF 24/176 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.291); catalogued as COSV56200653, COSV99945641; called by muse, mutect2, varscan2
- HBB | c.123G>T p.R41S | Missense Mutation (SNP) | VAF 15/115 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs33918778, CD951726, COSV100092899, COSV58942860; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HCFC1 | c.2122C>A p.Q708K | Missense Mutation (SNP) | VAF 37/75 reads (49%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.542); catalogued as COSV100129752; called by muse, mutect2, varscan2
- HEATR5A | c.3176A>G p.H1059R | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV101120456; called by muse, mutect2, varscan2
- HFM1 | c.4072G>T p.G1358* | Nonsense Mutation (SNP) | VAF 43/205 reads (21%) | catalogued as COSV99646648; called by muse, mutect2, varscan2
- HNRNPH3 | c.151G>C p.D51H | Missense Mutation (SNP) | VAF 33/233 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99769853; called by muse, mutect2, varscan2
- IGHV4-31 | c.185C>T p.P62L | Missense Mutation (SNP) | VAF 132/309 reads (43%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.165); catalogued as rs755702102; called by muse, mutect2, varscan2
- INPP5D | c.89T>C p.V30A | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV100856901; called by muse, mutect2, varscan2
- INSYN1 | c.77G>T p.R26L | Missense Mutation (SNP) | VAF 25/158 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101138824, COSV65837227; called by muse, mutect2, varscan2
- IRF6 | c.271A>G p.R91G | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100884026; called by muse, mutect2, varscan2
- JPH2 | c.935T>A p.L312H | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100881793; called by muse, mutect2, varscan2
- KIF26B | c.1498A>G p.N500D | Missense Mutation (SNP) | VAF 57/166 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.158); catalogued as COSV100833257; called by muse, mutect2, varscan2
- KIF5B | c.1363G>T p.D455Y | Missense Mutation (SNP) | VAF 46/217 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.927); catalogued as COSV100192308; called by muse, mutect2, varscan2
- KLC2 | c.218G>C p.G73A | Missense Mutation (SNP) | VAF 6/65 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.85); catalogued as COSV100385211; called by muse, mutect2
- KMT2D | c.4138T>G p.C1380G | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM1312956, COSV56427025, COSV99985276; called by muse, mutect2, varscan2
- KRT16 | c.609G>C p.R203S | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV100053030, COSV56966983; called by muse, mutect2, varscan2
- KRT33A | c.1037G>A p.R346Q | Missense Mutation (SNP) | VAF 65/219 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.192); catalogued as rs531059257, COSV99144995; called by muse, mutect2, varscan2
- KRTAP26-1 | c.268A>T p.R90W | Missense Mutation (SNP) | VAF 48/163 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100860472; called by muse, mutect2, varscan2
- L3MBTL1 | c.523C>G p.P175A (on ENST00000418998 / NM_001377303.1; = p.P85A on NM_015478.7) | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.167); catalogued as COSV100917303, COSV64234939; called by muse, mutect2, varscan2
- LNPEP | c.1213C>A p.Q405K | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.326); catalogued as COSV99183596; called by muse, mutect2, varscan2
- LRFN5 | c.2072C>A p.T691K | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.011); catalogued as rs369488450, COSV53254589, COSV53260302; called by muse, mutect2, varscan2
- LRP1B | c.9603G>T p.M3201I | Missense Mutation (SNP) | VAF 38/161 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.914); catalogued as COSV101259967, COSV67279430; called by muse, mutect2, varscan2
- LRRIQ1 | c.1354G>A p.D452N | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT tolerated (0.48); PolyPhen benign (0.015); catalogued as COSV101280688; called by muse, mutect2, varscan2
- LRRK2 | c.2498C>T p.T833I | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV54152627; called by muse, mutect2, varscan2
- LRRK2 | c.3857A>T p.N1286I | Missense Mutation (SNP) | VAF 30/102 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV100110999; called by muse, mutect2, varscan2
- LRRK2 | c.5948+2T>A p.X1983_splice | Splice Site (SNP) | VAF 21/74 reads (28%) | catalogued as COSV100111000; called by muse, mutect2, varscan2
- LTA4H | c.1171C>G p.L391V | Missense Mutation (SNP) | VAF 35/213 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV99957249; called by muse, mutect2, varscan2
- LUZP2 | c.623A>G p.E208G | Missense Mutation (SNP) | VAF 48/293 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV100421101; called by muse, mutect2, varscan2
- MACF1 | c.18188T>C p.I6063T (on ENST00000372915; = p.I4108T on NM_012090.5) | Missense Mutation (SNP) | VAF 14/104 reads (13%) | catalogued as COSV99246386; called by muse, mutect2, varscan2
- MAGEB3 | c.35G>C p.R12P | Missense Mutation (SNP) | VAF 32/58 reads (55%) | SIFT tolerated (0.1); PolyPhen benign (0.019); catalogued as COSV100854790; called by muse, mutect2, varscan2
- MATN2 | c.1289G>A p.R430H | Missense Mutation (SNP) | VAF 61/161 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.238); catalogued as rs199953090, COSV54706163; called by muse, mutect2, varscan2
- METTL22 | c.742G>A p.A248T | Missense Mutation (SNP) | VAF 17/126 reads (13%) | SIFT tolerated (0.35); PolyPhen benign (0.026); catalogued as COSV99371854; called by muse, mutect2, varscan2
- MFN2 | c.1029_1031del p.R344del | In Frame Del (DEL) | VAF 34/327 reads (10%) | catalogued as rs770137057; called by pindel, varscan2
- MPP4 | c.853C>T p.L285F | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.599); catalogued as COSV100207271; called by mutect2, varscan2
- MS4A14 | c.896C>A p.A299E | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.022); catalogued as COSV100280698; called by muse, mutect2, varscan2
- MS4A7 | c.227A>G p.N76S | Missense Mutation (SNP) | VAF 17/333 reads (5%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV55730937; called by muse, mutect2
- MSRB2 | c.365C>T p.S122F | Missense Mutation (SNP) | VAF 34/140 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.706); catalogued as COSV100919724; called by muse, mutect2
- MUC16 | c.4019C>A p.T1340K | Missense Mutation (SNP) | VAF 36/84 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV101201207; called by muse, mutect2, varscan2
- MUC5B | c.9061C>T p.P3021S | Missense Mutation (SNP) | VAF 60/231 reads (26%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.641); catalogued as rs1464120623, COSV101500682; called by muse, mutect2, varscan2
- MYBPC1 | c.2336-1G>C p.X779_splice (on ENST00000550270 / NM_206820.2; = p.X786_splice on NM_002465.4) | Splice Site (SNP) | VAF 18/100 reads (18%) | catalogued as rs112624063, COSV100638237; called by muse, mutect2, varscan2
- MYH2 | c.5241G>A p.M1747I | Missense Mutation (SNP) | VAF 39/117 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV55449650; called by muse, mutect2, varscan2
- MYH6 | c.5039A>G p.N1680S | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT tolerated (0.45); PolyPhen benign (0.088); catalogued as COSV100676930; called by muse, mutect2, varscan2
- MYH8 | c.1885A>C p.S629R | Missense Mutation (SNP) | VAF 33/84 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.189); catalogued as COSV101238672; called by muse, mutect2, varscan2
- NAV3 | c.149C>A p.S50Y | Missense Mutation (SNP) | VAF 14/126 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.365); catalogued as COSV99894695; called by mutect2, varscan2
- NAV3 | c.5459A>G p.E1820G (on ENST00000397909 / NM_001024383.2; = p.E1798G on NM_014903.6) | Missense Mutation (SNP) | VAF 32/162 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.577); catalogued as COSV99894701; called by muse, mutect2, varscan2
- NCDN | c.445C>T p.R149C | Missense Mutation (SNP) | VAF 38/232 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.696); catalogued as rs767974563, COSV57850938, COSV57851480; called by muse, mutect2, varscan2
- NDN | c.896A>G p.E299G | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.179); catalogued as COSV100086680; called by muse, varscan2
- NELFA | c.324G>C p.L108F (on ENST00000542778; = p.L97F on NM_005663.5) | Missense Mutation (SNP) | VAF 40/163 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.557); catalogued as COSV61610118; called by muse, mutect2, varscan2
- NF1 | c.3652C>T p.Q1218* | Nonsense Mutation (SNP) | VAF 43/122 reads (35%) | catalogued as COSV62205085; called by muse, mutect2, varscan2
- NLRP12 | c.728G>T p.R243I | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV60743254; called by muse, mutect2, varscan2
- NOBOX | c.320C>T p.A107V | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.014); catalogued as COSV56194618; called by muse, mutect2, varscan2
- NRK | c.4295G>A p.G1432E | Missense Mutation (SNP) | VAF 46/83 reads (55%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs267606301, COSV99688965; called by muse, mutect2, varscan2
- NSMF | c.603G>T p.R201S | Missense Mutation (SNP) | VAF 9/99 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.974); catalogued as COSV99481293; called by muse, mutect2, varscan2
- NUBP2 | c.178C>T p.R60C | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as rs200532876, COSV51906133, COSV51907719; called by muse, mutect2, varscan2
- NUTM1 | c.1072G>T p.E358* | Nonsense Mutation (SNP) | VAF 12/92 reads (13%) | catalogued as COSV100149181; called by muse, mutect2, varscan2
- OAZ1 | c.255G>T p.Q85H | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.825); catalogued as COSV100457435, COSV59233261; called by muse, mutect2, varscan2
- OGT | c.1767C>G p.F589L | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); catalogued as COSV101035587; called by muse, mutect2, varscan2
- OR1E2 | c.745A>T p.T249S | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.687); catalogued as COSV99943492; called by muse, mutect2, varscan2
- OR2T10 | c.482C>T p.P161L | Missense Mutation (SNP) | VAF 68/165 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.02); catalogued as rs147074156, COSV57896206; called by muse, mutect2, varscan2
- OR4K2 | c.413C>A p.P138H | Missense Mutation (SNP) | VAF 53/390 reads (14%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV100064706; called by muse, mutect2, varscan2
- OR56B4 | c.863C>A p.P288H | Missense Mutation (SNP) | VAF 20/157 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100337688; called by muse, mutect2, varscan2
- OR6T1 | c.482T>C p.V161A | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.026); catalogued as COSV100190150; called by muse, mutect2, varscan2
- OR8B12 | c.691G>A p.E231K | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.17); catalogued as COSV100172915, COSV60913036; called by muse, mutect2
- OR8G5 | c.390G>T p.L130F | Missense Mutation (SNP) | VAF 22/201 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100422613; called by muse, mutect2, varscan2
- OR9K2 | c.421G>A p.A141T (on ENST00000305377; = p.A119T on NM_001005243.1) | Missense Mutation (SNP) | VAF 20/126 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.899); catalogued as COSV59533376; called by muse, mutect2, varscan2
- P4HA1 | c.1286A>G p.H429R | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99697179; called by muse, mutect2, varscan2
- PADI3 | c.59T>C p.V20A | Missense Mutation (SNP) | VAF 10/131 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV100968573; called by muse, mutect2
- PALM | c.775dup p.A259Gfs*53 | Frame Shift Ins (INS) | VAF 6/40 reads (15%) | catalogued as rs755308979; called by pindel, varscan2
- PCDHA2 | c.1371G>T p.Q457H | Missense Mutation (SNP) | VAF 41/121 reads (34%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.502); catalogued as COSV100974121; called by muse, mutect2, varscan2
- PCDHB14 | c.481G>T p.D161Y | Missense Mutation (SNP) | VAF 40/128 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV53390296, COSV99506216; called by muse, mutect2, varscan2
- PCDHGB7 | c.1400C>T p.P467L | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.67); catalogued as rs765877993, COSV53897314; called by muse, mutect2
- PDZRN4 | c.3052G>T p.A1018S (on ENST00000402685 / NM_001164595.2; = p.A760S on NM_013377.4) | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT tolerated (0.35); PolyPhen benign (0.052); catalogued as COSV100114636; called by muse, mutect2, varscan2
- PEX1 | c.2374A>G p.I792V | Missense Mutation (SNP) | VAF 40/614 reads (7%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as rs755913199, COSV99952328; called by muse, mutect2
- PHKA1 | c.3107C>T p.S1036F | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.635); catalogued as COSV100263267, COSV59802020; called by muse, mutect2, varscan2
- PIGG | c.1294A>C p.I432L | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV99574271; called by muse, mutect2, varscan2
- PIM3 | c.790C>G p.P264A | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV100638424, COSV100638443; called by muse, mutect2, varscan2
- PLB1 | c.2791G>A p.V931I | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs371954478; called by muse, mutect2, varscan2
- PLEKHF1 | c.304A>G p.I102V | Missense Mutation (SNP) | VAF 11/128 reads (9%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.773); catalogued as COSV101460795; called by muse, mutect2
- PPDPFL | c.78T>G p.S26R | Missense Mutation (SNP) | VAF 8/186 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.319); catalogued as COSV100293229; called by muse, mutect2
- PRB4 | c.271G>T p.G91C | Missense Mutation (SNP) | VAF 86/674 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.777); catalogued as rs1063751; called by muse, varscan2
- PROS1 | c.1952T>C p.L651P | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101260768; called by muse, mutect2, varscan2
- PTPRC | c.100G>T p.G34* | Nonsense Mutation (SNP) | VAF 20/70 reads (29%) | catalogued as COSV100723048; called by muse, mutect2, varscan2
- PTPRJ | c.955C>T p.P319S | Missense Mutation (SNP) | VAF 82/293 reads (28%) | SIFT tolerated (0.61); PolyPhen benign (0.01); catalogued as COSV101395727; called by muse, mutect2, varscan2
- PTPRM | c.1099G>T p.G367C | Missense Mutation (SNP) | VAF 14/126 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100159782; called by muse, mutect2
- PTPRT | c.634C>G p.Q212E | Missense Mutation (SNP) | VAF 44/510 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV100629976; called by muse, mutect2
- PYROXD2 | c.1687A>G p.M563V | Missense Mutation (SNP) | VAF 72/199 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.118); catalogued as COSV100996103; called by muse, mutect2, varscan2
- RALGAPB | c.3657G>T p.W1219C | Missense Mutation (SNP) | VAF 61/196 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99485684; called by muse, mutect2, varscan2
- RIPOR3 | c.237A>T p.E79D | Missense Mutation (SNP) | VAF 28/137 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.037); catalogued as COSV99247055; called by muse, mutect2, varscan2
- RNASE8 | c.382C>A p.P128T | Missense Mutation (SNP) | VAF 58/299 reads (19%) | SIFT tolerated (0.35); PolyPhen benign (0.071); catalogued as COSV100373522, COSV100373536; called by muse, mutect2, varscan2
- RPL3L | c.942C>G p.I314M | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99238456; called by muse, mutect2, varscan2
- RRP8 | c.760C>G p.L254V | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.696); catalogued as COSV99602027; called by muse, mutect2
- SACS | c.3601C>G p.L1201V | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.589); catalogued as COSV101207671, COSV66547269; called by muse, mutect2, varscan2
- SASS6 | c.898C>T p.R300* | Nonsense Mutation (SNP) | VAF 18/134 reads (13%) | catalogued as COSV54929186; called by muse, mutect2, varscan2
- SDHD | c.386T>C p.L129S | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.159); catalogued as rs201726097, COSV65019515; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SEMA5A | c.3173A>T p.K1058M | Missense Mutation (SNP) | VAF 23/128 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); catalogued as COSV101228670, COSV66784987; called by muse, mutect2, varscan2
- SF3A1 | c.2096G>T p.R699L | Missense Mutation (SNP) | VAF 86/195 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV53167388, COSV99305679; called by muse, mutect2, varscan2
- SFRP4 | c.529C>A p.R177= | Splice Region (SNP) | VAF 26/87 reads (30%) | catalogued as COSV101460943, COSV71412372; called by muse, mutect2, varscan2
- SI | c.1802G>T p.W601L | Missense Mutation (SNP) | VAF 40/238 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52272917; called by muse, mutect2, varscan2
- SI | c.142C>A p.P48T | Missense Mutation (SNP) | VAF 31/193 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.026); catalogued as COSV100016856; called by muse, mutect2, varscan2
- SLC12A7 | c.3003C>G p.F1001L | Missense Mutation (SNP) | VAF 102/358 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs941291923, COSV53757347, COSV99370459; called by muse, mutect2, varscan2
- SLC22A8 | c.1497del p.L500Cfs*63 | Frame Shift Del (DEL) | VAF 38/182 reads (21%) | catalogued as COSV60327788; called by mutect2, pindel, varscan2
- SLC44A5 | c.1529+1G>C p.X510_splice | Splice Site (SNP) | VAF 78/269 reads (29%) | catalogued as COSV100902475; called by muse, mutect2, varscan2
- SLITRK4 | c.826C>A p.P276T | Missense Mutation (SNP) | VAF 54/113 reads (48%) | SIFT tolerated (0.33); PolyPhen benign (0.119); catalogued as COSV100567481, COSV62022235; called by muse, mutect2, varscan2
- SNRNP200 | c.884C>T p.T295M | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.018); catalogued as rs368983658; called by muse, mutect2, varscan2
- SOHLH2 | c.1246C>A p.P416T | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.154); catalogued as COSV101157984, COSV65903877; called by muse, mutect2, varscan2
- SPEG | c.1084G>T p.G362W | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.035); catalogued as COSV100405443; called by muse, mutect2, varscan2
- SPPL2C | c.1573T>C p.F525L | Missense Mutation (SNP) | VAF 43/151 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.651); catalogued as COSV100234134; called by muse, mutect2, varscan2
- SPTBN4 | c.4586C>T p.A1529V | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.192); catalogued as COSV100151896; called by muse, mutect2, varscan2
- SSR1 | c.671G>C p.G224A | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.46); catalogued as COSV99783815; called by muse, mutect2, varscan2
- SYNE2 | c.10360C>G p.L3454V | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.283); catalogued as COSV100648381; called by muse, mutect2, varscan2
- TACR3 | c.565G>T p.D189Y | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.06); catalogued as rs201823274, COSV100510474, COSV100510863; called by muse, mutect2, varscan2
- TECTA | c.5699A>G p.Y1900C | Missense Mutation (SNP) | VAF 77/240 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99881279; called by muse, mutect2, varscan2
- TIGD4 | c.57A>C p.K19N | Missense Mutation (SNP) | VAF 24/132 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); catalogued as COSV100428048; called by muse, mutect2, varscan2
- TMIGD2 | c.650G>A p.R217K | Missense Mutation (SNP) | VAF 17/131 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs574674268, COSV100010489; called by muse, mutect2, varscan2
- TTLL7 | c.793A>T p.T265S | Missense Mutation (SNP) | VAF 34/200 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.44); catalogued as COSV99553021; called by muse, mutect2, varscan2
- TTN | c.49222A>G p.N16408D (on ENST00000591111; = p.N8984D on NM_003319.4) | Missense Mutation (SNP) | VAF 46/341 reads (13%) | PolyPhen probably damaging (0.994); catalogued as COSV100626588; called by muse, mutect2, varscan2
- UGT1A7 | c.719C>T p.T240M | Missense Mutation (SNP) | VAF 97/656 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs371311391; called by muse, mutect2, varscan2
- UHRF1BP1 | c.3039C>G p.N1013K | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.141); catalogued as COSV99512388; called by muse, mutect2, varscan2
- UHRF1BP1L | c.3844A>G p.I1282V | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as rs201390016, COSV99692051; called by muse, mutect2, varscan2
- UMOD | c.1856G>C p.S619T | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.54); PolyPhen benign (0.018); catalogued as COSV100208611; called by muse, mutect2, varscan2
- VPS13A | c.2295G>C p.K765N | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100653366; called by muse, mutect2
- WBP11 | c.1363C>T p.P455S | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.992); catalogued as COSV99660844; called by muse, mutect2
- WDFY3 | c.330G>C p.Q110H | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.805); catalogued as COSV99885250; called by muse, mutect2
- WDR91 | c.1640C>T p.T547M | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.53); catalogued as rs139497978; called by muse, mutect2
- WIF1 | c.377C>A p.T126K | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.53); PolyPhen benign (0.058); catalogued as COSV99683351; called by muse, varscan2
- WRN | c.155C>T p.S52F | Missense Mutation (SNP) | VAF 33/328 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as COSV99989722; called by muse, mutect2, varscan2
- ZBP1 | c.874+1G>T p.X292_splice | Splice Site (SNP) | VAF 10/27 reads (37%) | catalogued as COSV100473841; called by muse, mutect2, varscan2
- ZC3H6 | c.833G>T p.C278F | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100674804; called by muse, varscan2
- ZFHX4 | c.8105G>T p.G2702V | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.882); catalogued as rs369317859, COSV51484165; called by muse, mutect2, varscan2
- ZHX1 | c.2153G>T p.G718V | Missense Mutation (SNP) | VAF 63/175 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV99933841; called by muse, mutect2, varscan2
- ZHX1 | c.2152G>T p.G718* | Nonsense Mutation (SNP) | VAF 62/175 reads (35%) | catalogued as COSV99933844; called by muse, mutect2, varscan2
- ZNF479 | c.724A>G p.R242G | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV100483005; called by muse, mutect2, varscan2
- ZNF532 | c.2233G>A p.D745N | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs1391284376, COSV100267076; called by muse, mutect2, varscan2
- ZZEF1 | c.6655C>T p.R2219C | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs752808355, COSV101067478; called by muse, mutect2, varscan2
- BACE2 | c.1411_1417del p.V471Mfs*4 | Frame Shift Del (DEL) | VAF 12/62 reads (19%) | called by mutect2, pindel, varscan2
- FAT1 | c.7851dup p.V2618Sfs*5 | Frame Shift Ins (INS) | VAF 11/46 reads (24%) | called by mutect2, pindel, varscan2
- GPC5 | c.525del p.Y175* | Frame Shift Del (DEL) | VAF 47/205 reads (23%) | called by mutect2, pindel, varscan2
- IGLV1-51 | c.80C>G p.P27R | Missense Mutation (SNP) | VAF 61/136 reads (45%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- IL1RAP | c.1110_1112del p.V372del | In Frame Del (DEL) | VAF 17/90 reads (19%) | called by mutect2, pindel, varscan2
- KIF16B | c.1367dup p.L456Ffs*6 | Frame Shift Ins (INS) | VAF 41/144 reads (28%) | called by mutect2, pindel, varscan2
- MINAR1 | c.2228del p.G743Afs*7 | Frame Shift Del (DEL) | VAF 13/91 reads (14%) | called by mutect2, pindel, varscan2
- NELL2 | c.1830dup p.H611Afs*6 | Frame Shift Ins (INS) | VAF 37/143 reads (26%) | called by mutect2, pindel, varscan2
- SCN2A | c.1935del p.H645Qfs*36 | Frame Shift Del (DEL) | VAF 6/50 reads (12%) | called by mutect2, pindel, varscan2
- ZNF658 | c.464G>T p.S155I | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.32); PolyPhen benign (0.007); called by mutect2, varscan2
- ACACB | c.648T>A p.T216= | Silent (SNP) | VAF 9/60 reads (15%) | catalogued as COSV100623243; called by muse, mutect2, varscan2
- ACTRT1 | c.1005T>C p.D335= | Silent (SNP) | VAF 20/96 reads (21%) | catalogued as COSV64420288; called by muse, mutect2, varscan2
- ADAMTS16 | c.1035A>C p.L345= | Silent (SNP) | VAF 18/239 reads (8%) | catalogued as COSV99942611; called by muse, mutect2
- AMBRA1 | c.678T>C p.R226= | Silent (SNP) | VAF 27/113 reads (24%) | catalogued as COSV100095159; called by muse, mutect2, varscan2
- ATF7IP | c.2679C>T p.G893= | Silent (SNP) | VAF 8/51 reads (16%) | catalogued as COSV99662053; called by muse, mutect2, varscan2
- CARD17 | c.195G>T p.G65= | Silent (SNP) | VAF 24/120 reads (20%) | catalogued as rs1410001617, COSV100995277; called by muse, mutect2, varscan2
- CEACAM20 | c.1678C>T p.L560= | Silent (SNP) | VAF 22/72 reads (31%) | catalogued as rs748031361, COSV57601173; called by muse, mutect2, varscan2
- CEP97 | c.1236G>C p.L412= | Silent (SNP) | VAF 15/107 reads (14%) | catalogued as COSV100512038; called by muse, mutect2, varscan2
- CHST6 | c.333G>A p.L111= | Silent (SNP) | VAF 20/59 reads (34%) | catalogued as COSV100178578; called by muse, mutect2, varscan2
- CSMD2 | c.1947A>T p.S649= | Silent (SNP) | VAF 14/101 reads (14%) | catalogued as COSV99587317; called by muse, mutect2, varscan2
- CUBN | c.2199A>G p.Q733= | Silent (SNP) | VAF 22/61 reads (36%) | catalogued as rs375371074; called by muse, mutect2, varscan2
- DNAH7 | c.6150T>A p.A2050= | Silent (SNP) | VAF 33/115 reads (29%) | catalogued as COSV100417089; called by muse, mutect2, varscan2
- DPY19L2 | c.1977A>G p.P659= | Silent (SNP) | VAF 17/144 reads (12%) | catalogued as rs975486527, COSV100193954; called by muse, varscan2
- DYSF | c.1125C>A p.A375= | Silent (SNP) | VAF 41/309 reads (13%) | catalogued as COSV99250012; called by muse, mutect2, varscan2
- ERICH3 | c.1974G>A p.P658= | Silent (SNP) | VAF 27/137 reads (20%) | catalogued as rs774666353, COSV100444877; called by muse, mutect2, varscan2
- ERMAP | c.1398C>G p.A466= | Silent (SNP) | VAF 10/84 reads (12%) | catalogued as COSV100072366; called by muse, mutect2
- FAM71B | c.267G>C p.L89= | Silent (SNP) | VAF 27/98 reads (28%) | catalogued as COSV100262271; called by muse, mutect2, varscan2
- FBF1 | c.1050C>T p.D350= (on ENST00000586717; = p.D364= on NM_001319193.1) | Silent (SNP) | VAF 8/23 reads (35%) | catalogued as rs541926169, COSV59863861; called by muse, mutect2, varscan2
- GABRG1 | c.477C>T p.H159= | Silent (SNP) | VAF 35/142 reads (25%) | catalogued as COSV54954280; called by muse, mutect2, varscan2
- GAS2L2 | c.1440T>C p.G480= | Silent (SNP) | VAF 32/108 reads (30%) | catalogued as rs782448416; called by muse, mutect2, varscan2
- GPHN | c.417G>A p.T139= | Silent (SNP) | VAF 9/99 reads (9%) | catalogued as rs763888545, COSV100017478; called by muse, mutect2, varscan2
- GRM8 | c.1491A>G p.L497= | Silent (SNP) | VAF 47/248 reads (19%) | catalogued as COSV100285456; called by muse, mutect2, varscan2
- HOXA2 | c.210C>A p.G70= | Silent (SNP) | VAF 6/15 reads (40%) | catalogued as rs1469545507, COSV56065067, COSV99761386; called by muse, mutect2, varscan2
- HPSE2 | c.996C>T p.T332= | Silent (SNP) | VAF 48/141 reads (34%) | catalogued as COSV100986164; called by muse, mutect2, varscan2
- HRNR | c.1080C>T p.G360= | Silent (SNP) | VAF 80/238 reads (34%) | catalogued as rs1197444597, COSV100913861; called by muse, mutect2, varscan2
- IGKV2D-29 | c.27G>T p.G9= | Silent (SNP) | VAF 23/179 reads (13%) | called by muse, mutect2, varscan2
- ISLR2 | c.2190C>A p.V730= | Silent (SNP) | VAF 9/67 reads (13%) | catalogued as COSV100679741; called by muse, mutect2, varscan2
- KIDINS220 | c.4293A>G p.L1431= | Silent (SNP) | VAF 33/227 reads (15%) | catalogued as COSV99876307; called by muse, mutect2, varscan2
- KIF25 | c.456C>A p.A152= | Silent (SNP) | VAF 51/104 reads (49%) | catalogued as COSV100596464; called by muse, mutect2, varscan2
- KMT2E | c.4662G>A p.S1554= | Silent (SNP) | VAF 166/244 reads (68%) | catalogued as rs757593144, COSV99995666, COSV99996886; called by muse, mutect2, varscan2
- KSR2 | c.921G>T p.A307= | Silent (SNP) | VAF 36/233 reads (15%) | catalogued as COSV60366314, COSV60391623; called by muse, mutect2, varscan2
- MRPL1 | c.522A>G p.G174= | Silent (SNP) | VAF 40/162 reads (25%) | catalogued as COSV100214016; called by muse, mutect2, varscan2
- MUC16 | c.15879C>A p.S5293= | Silent (SNP) | VAF 60/122 reads (49%) | catalogued as COSV101200686, COSV101201206; called by muse, mutect2, varscan2
- MXRA5 | c.6882C>T p.S2294= | Silent (SNP) | VAF 39/80 reads (49%) | catalogued as rs767514233, COSV99478849; called by muse, mutect2, varscan2
- NAV3 | c.150C>A p.S50= | Silent (SNP) | VAF 14/126 reads (11%) | catalogued as COSV99894696; called by mutect2, varscan2
- NCAN | c.2217C>A p.V739= | Silent (SNP) | VAF 49/190 reads (26%) | catalogued as COSV53047635; called by muse, mutect2, varscan2
- NEO1 | c.4206C>T p.I1402= | Silent (SNP) | VAF 10/61 reads (16%) | catalogued as rs553567223, COSV99982505; called by muse, mutect2, varscan2
- NRIP3 | c.204C>G p.L68= | Silent (SNP) | VAF 20/94 reads (21%) | catalogued as COSV100487252; called by muse, mutect2, varscan2
- OR13C9 | c.720C>T p.T240= | Silent (SNP) | VAF 30/119 reads (25%) | catalogued as COSV99403548; called by muse, mutect2, varscan2
- OR1L4 | c.825C>T p.A275= | Silent (SNP) | VAF 21/149 reads (14%) | catalogued as COSV99413939; called by muse, mutect2, varscan2
- OR2T27 | c.435G>T p.V145= | Silent (SNP) | VAF 58/193 reads (30%) | catalogued as COSV100788362; called by muse, mutect2, varscan2
- OR52J3 | c.771C>A p.V257= | Silent (SNP) | VAF 52/211 reads (25%) | catalogued as COSV100984899, COSV66747654; called by muse, mutect2, varscan2
- OR5B17 | c.558C>A p.T186= | Silent (SNP) | VAF 33/94 reads (35%) | catalogued as COSV100641953; called by muse, mutect2, varscan2
- OTOA | c.1470T>C p.S490= (on ENST00000286149; = p.S476= on NM_144672.4) | Silent (SNP) | VAF 55/462 reads (12%) | catalogued as rs768356060, COSV99625595; called by muse, mutect2, varscan2
- RNF40 | c.249G>T p.R83= | Silent (SNP) | VAF 7/119 reads (6%) | called by muse, mutect2
- RTN4 | c.996G>A p.E332= | Silent (SNP) | VAF 13/41 reads (32%) | catalogued as COSV100463815; called by muse, mutect2, varscan2
- SEC16B | c.2256T>C p.P752= | Silent (SNP) | VAF 3/19 reads (16%) | catalogued as COSV100381871; called by muse, mutect2
- SIDT1 | c.2483G>A p.*828= | Silent (SNP) | VAF 26/153 reads (17%) | catalogued as COSV99334554; called by muse, mutect2, varscan2
- SLC39A10 | c.2436T>C p.F812= | Silent (SNP) | VAF 62/239 reads (26%) | catalogued as COSV100417085; called by muse, mutect2, varscan2
- SLC6A2 | c.1626A>G p.P542= | Silent (SNP) | VAF 106/258 reads (41%) | catalogued as COSV99574467; called by muse, mutect2, varscan2
- SLITRK5 | c.927C>A p.T309= | Silent (SNP) | VAF 35/119 reads (29%) | catalogued as COSV100281115; called by muse, mutect2, varscan2
- SPTBN1 | c.6597G>A p.Q2199= | Silent (SNP) | VAF 39/119 reads (33%) | catalogued as COSV100443294; called by muse, mutect2, varscan2
- STYXL2 | c.936G>A p.L312= | Silent (SNP) | VAF 8/13 reads (62%) | catalogued as COSV99609781; called by muse, mutect2, varscan2
- SULT1C3 | c.267C>T p.F89= | Silent (SNP) | VAF 20/87 reads (23%) | catalogued as COSV100227574; called by muse, mutect2, varscan2
- TBC1D22B | c.1140G>A p.L380= | Silent (SNP) | VAF 39/161 reads (24%) | catalogued as COSV100996911; called by muse, mutect2, varscan2
- TNIK | c.1233A>G p.R411= | Silent (SNP) | VAF 26/217 reads (12%) | catalogued as COSV99459173; called by muse, mutect2, varscan2
- TUBB4B | c.861C>G p.P287= | Silent (SNP) | VAF 29/82 reads (35%) | catalogued as rs772348490, COSV100457695, COSV100458146, COSV100458149; called by muse, mutect2, varscan2
- TULP4 | c.1908G>T p.R636= | Silent (SNP) | VAF 78/153 reads (51%) | catalogued as COSV100893782; called by muse, mutect2, varscan2
- WEE2 | c.153A>G p.A51= | Silent (SNP) | VAF 67/335 reads (20%) | catalogued as COSV101285237; called by muse, mutect2, varscan2
- XRCC4 | c.900G>A p.R300= (on ENST00000338635 / NM_022406.4; = p.K298= on NM_003401.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 62/173 reads (36%) | catalogued as rs374723855; called by muse, mutect2, varscan2
- ZKSCAN2 | c.498G>A p.A166= | Silent (SNP) | VAF 18/74 reads (24%) | catalogued as rs200859388, COSV60157242; called by muse, mutect2, varscan2
- AC073310.1 | n.387A>G | RNA (SNP) | VAF 59/269 reads (22%) | catalogued as rs768712149; called by muse, mutect2, varscan2
- CSH1 | c.456+110A>T | Intron (SNP) | VAF 150/263 reads (57%) | catalogued as COSV100298433; called by muse, mutect2, varscan2
- HERC2P3 | n.893C>G | RNA (SNP) | VAF 26/372 reads (7%) | called by muse, mutect2
- MIR525 | n.85del | RNA (DEL) | VAF 7/57 reads (12%) | called by mutect2, pindel, varscan2
- SERPINA13P | n.1033C>A | RNA (SNP) | VAF 12/66 reads (18%) | called by muse, mutect2, varscan2
- TCP10L3 | n.529C>G | RNA (SNP) | VAF 19/203 reads (9%) | catalogued as COSV100833245; called by muse, mutect2, varscan2
